Somatic mutation profile of tumor specimen C3L-01689-02 (aliquot CPT0094740010) from CPTAC case C3L-01689, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 62.1 years (22,672 days).
Specimen C3L-01689-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a28b2c62-f102-48c8-8350-6bbd74812696.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01689-31 (Blood Derived Normal), aliquot CPT0094770002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cac96232-2b2a-49a2-92b5-54eb8a3fb1c9

The open-access MAF lists 48 somatic variants for this specimen: 39 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 4, Nonsense Mutation 4, RNA 3, Intron 2, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 73/409 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AATK | c.1538C>T p.P513L (on ENST00000326724 / NM_001080395.3; = p.P410L on NM_004920.2) | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs1416558474; called by muse, mutect2, varscan2
- APBB3 | c.1289G>A p.R430H (on ENST00000357560 / NM_133173.2; = p.R437H on NM_006051.3) | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.925); catalogued as rs755227669, COSV60366572; called by muse, mutect2, varscan2
- BCOR | c.4981C>T p.R1661* (on ENST00000378444 / NM_001123385.2; = p.R1627* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 21/112 reads (19%) | catalogued as COSV60702852; called by muse, mutect2, varscan2
- CEACAM5 | c.1861C>T p.P621S | Missense Mutation (SNP) | VAF 99/468 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55754853; called by muse, mutect2, varscan2
- CFAP221 | c.1576T>C p.F526L | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs764563519; called by muse, mutect2, varscan2
- EMILIN1 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1273581666, COSV104431032; called by muse, mutect2, varscan2
- FAM178B | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.8); catalogued as rs533483443, COSV59970237; called by muse, mutect2, varscan2
- GPR179 | c.961C>T p.R321* (on ENST00000621958; = p.R320* on NM_001004334.4) | Nonsense Mutation (SNP) | VAF 34/173 reads (20%) | catalogued as rs768587459; called by muse, mutect2, varscan2
- IFT57 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 37/265 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771681320, COSV52708404; called by muse, mutect2, varscan2
- KSR1 | c.1040C>T p.T347M (on ENST00000644974 / NM_001367810.1; = p.T210M on NM_014238.2) | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs369066812; called by muse, mutect2, varscan2
- KSR2 | c.544G>A p.V182M | Missense Mutation (SNP) | VAF 45/261 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100348492; called by muse, mutect2, varscan2
- RBM10 | c.2377C>T p.R793* | Nonsense Mutation (SNP) | VAF 105/328 reads (32%) | catalogued as COSV61307739; called by muse, mutect2, varscan2
- RYR2 | c.3167C>T p.T1056M | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs779146564, COSV63707037; called by muse, mutect2, varscan2
- SEC24B | c.317C>A p.T106K | Missense Mutation (SNP) | VAF 42/217 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV99494207; called by muse, mutect2, varscan2
- SYNE1 | c.3997C>T p.R1333C (on ENST00000367255 / NM_182961.4; = p.R1340C on NM_033071.3) | Missense Mutation (SNP) | VAF 71/405 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs1018039106, COSV54900080, COSV99549323; called by muse, mutect2, varscan2
- TP53 | c.128del p.L43* | Frame Shift Del (DEL) | VAF 55/263 reads (21%) | catalogued as COSV52992944; called by mutect2, pindel, varscan2
- ZNF229 | c.2036C>T p.T679M | Missense Mutation (SNP) | VAF 49/245 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); catalogued as rs754516445, COSV52159418; called by muse, mutect2, varscan2
- ACO2 | c.1161T>A p.N387K | Missense Mutation (SNP) | VAF 8/167 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- CERCAM | c.593C>A p.P198H | Missense Mutation (SNP) | VAF 64/357 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- DHX15 | c.698T>G p.L233R | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- DNAH9 | c.9073A>G p.T3025A | Missense Mutation (SNP) | VAF 44/251 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EXOC2 | c.1444-2A>T p.X482_splice | Splice Site (SNP) | VAF 16/153 reads (10%) | called by muse, mutect2, varscan2
- FBLN1 | c.506A>G p.E169G | Missense Mutation (SNP) | VAF 29/446 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.116); called by muse, mutect2
- GPT2 | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 32/163 reads (20%) | called by muse, mutect2, varscan2
- HGSNAT | c.1864A>G p.I622V | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.638); called by mutect2, varscan2
- HSPBP1 | c.308C>G p.P103R | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- IGSF10 | c.3493G>A p.V1165M | Missense Mutation (SNP) | VAF 36/302 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- IL13 | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KCNG1 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- KIF5A | c.2347C>A p.L783M | Missense Mutation (SNP) | VAF 84/506 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH7B | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 62/325 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- NAB2 | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- OTUD1 | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OVCH1 | c.3338C>T p.A1113V | Missense Mutation (SNP) | VAF 7/179 reads (4%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2
- SLC5A5 | c.1081G>C p.A361P | Missense Mutation (SNP) | VAF 87/588 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TIE1 | c.785G>A p.G262D | Missense Mutation (SNP) | VAF 121/281 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TLR10 | c.959A>G p.Y320C | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- ZNF417 | c.881C>T p.T294I | Missense Mutation (SNP) | VAF 56/326 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- H2BC6 | c.108G>A p.E36= | Silent (SNP) | VAF 22/569 reads (4%) | called by muse, mutect2
- LRRK1 | c.3046A>C p.R1016= | Silent (SNP) | VAF 50/325 reads (15%) | called by muse, mutect2, varscan2
- SEPTIN8 | c.939C>T p.S313= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as rs370048462; called by muse, mutect2, varscan2
- TENM3 | c.7440C>T p.A2480= | Silent (SNP) | VAF 13/285 reads (5%) | catalogued as rs1308009125; called by muse, mutect2
- AC025278.3 | n.25G>C | RNA (SNP) | VAF 30/159 reads (19%) | called by muse, mutect2, varscan2
- FAM90A20P | n.584C>T | RNA (SNP) | VAF 103/421 reads (24%) | called by muse, mutect2, varscan2
- MCM2 | c.1428+1798G>A | Intron (SNP) | VAF 68/397 reads (17%) | called by muse, mutect2, varscan2
- OR5P1P | n.754G>A | RNA (SNP) | VAF 13/218 reads (6%) | catalogued as rs1243689906; called by muse, mutect2
- PMPCA | c.1263+72G>T | Intron (SNP) | VAF 29/158 reads (18%) | called by muse, mutect2, varscan2
